FM case AD17151 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/cd19ec8c-f508-4282-bf40-6f8e3ae98626

Male, 64.8 years: Carcinoma, NOS (ICD-O-3 8010/3) of the thyroid gland; metastasis biopsied or resected from the thyroid gland. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
